Somatic mutation profile of tumor specimen TCGA-33-4533-01A (aliquot TCGA-33-4533-01A-01D-1267-08) from TCGA case TCGA-33-4533, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.7 years (28,001 days).
Specimen TCGA-33-4533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06685122-cbbb-43cc-af35-43d50fab0a80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4533-11A (Solid Tissue Normal), aliquot TCGA-33-4533-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7764ff75-9297-45c9-a757-42e281a2c539

The open-access MAF lists 306 somatic variants for this specimen: 239 protein-altering or splice-affecting, 54 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 54, Nonsense Mutation 16, Frame Shift Del 10, Splice Site 6, Intron 5, 3'UTR 3, RNA 2, 5'Flank 2, Translation Start Site 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.265-2A>G p.X89_splice | Splice Site (SNP) | VAF 49/61 reads (80%) | hotspot (GDC flag); catalogued as CS050403, CS158897, COSV57295563, COSV57312830, COSV57318130; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 180/248 reads (73%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 205/260 reads (79%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.759); catalogued as COSV64102406; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 111/207 reads (54%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV58441232; called by muse, mutect2, varscan2
- ADGRB3 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs1004615310, COSV65382168; called by muse, mutect2, varscan2
- ADGRV1 | c.13003G>T p.V4335F | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV67978219; called by muse, mutect2, varscan2
- ADGRV1 | c.14740A>T p.T4914S | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV67978221; called by muse, mutect2, varscan2
- AKT1S1 | c.635C>T p.S212L (on ENST00000344175 / NM_001098633.4; = p.S232L on NM_032375.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs1172356384, COSV59274112; called by muse, mutect2, varscan2
- ANKS1A | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 147/355 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV64458744; called by muse, mutect2, varscan2
- ANKS6 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT tolerated (0.63); PolyPhen probably damaging (1); catalogued as rs1011234742, COSV62048781; called by muse, mutect2, varscan2
- ANO4 | c.2803C>A p.R935S (on ENST00000392977 / NM_001286615.2; = p.R900S on NM_178826.4) | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as COSV54585067; called by muse, mutect2, varscan2
- ANOS1 | c.1985G>T p.R662I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV52915821; called by muse, mutect2, varscan2
- AOPEP | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV52914488; called by muse, mutect2, varscan2
- ARMCX5 | c.635A>T p.K212I | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55765870; called by muse, mutect2
- ASB5 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 100/157 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56668472; called by muse, varscan2
- ATG2B | c.3973G>A p.D1325N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.5); catalogued as COSV55889386, COSV55890434; called by muse, mutect2
- ATP6V1B1 | c.1062T>A p.D354E | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52268177; called by muse, mutect2, varscan2
- ATRX | c.5891G>C p.G1964A | Missense Mutation (SNP) | VAF 22/429 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV64871218; called by muse, mutect2
- BTNL8 | c.1460C>A p.S487Y | Missense Mutation (SNP) | VAF 92/120 reads (77%) | SIFT tolerated (0.35); PolyPhen benign (0.078); catalogued as COSV51456760; called by muse, mutect2, varscan2
- C1QL3 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV54348127; called by muse, mutect2, varscan2
- CADM2 | c.536G>T p.R179L (on ENST00000407528 / NM_001167674.2; = p.R181L on NM_153184.4) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV67356966, COSV67406817; called by muse, mutect2, varscan2
- CCDC170 | c.1405G>T p.V469F | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV53336501; called by muse, mutect2, varscan2
- CCDC85A | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV68147510; called by muse, mutect2, varscan2
- CDH24 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV57458441; called by muse, mutect2, varscan2
- CDHR2 | c.1763G>C p.G588A | Missense Mutation (SNP) | VAF 91/137 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV56134541; called by muse, mutect2, varscan2
- CELSR3 | c.2086G>C p.D696H | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV50839813; called by muse, mutect2, varscan2
- CENPF | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV65272608; called by muse, mutect2, varscan2
- CETN1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs774527376, COSV59120838; called by muse, mutect2, varscan2
- CFAP43 | c.2559T>A p.H853Q | Missense Mutation (SNP) | VAF 75/100 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53376191; called by muse, mutect2, varscan2
- CFAP46 | c.6829C>A p.Q2277K | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54148369; called by muse, varscan2
- CGN | c.1518G>C p.E506D | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs1440103708, COSV54967895; called by muse, mutect2, varscan2
- CLCA1 | c.212G>C p.R71P | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753995315, COSV52324938, COSV52328286; called by muse, mutect2, varscan2
- COL3A1 | c.2717G>T p.G906V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58581775; called by muse, mutect2, varscan2
- CPT2 | c.1205A>C p.Q402P | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV53758643; called by muse, mutect2, varscan2
- CSF2RB | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as COSV53255417, COSV99453140; called by muse, mutect2, varscan2
- CSMD3 | c.8515G>T p.V2839F (on ENST00000297405 / NM_001363185.1; = p.V2670F on NM_052900.3) | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52100138; called by muse, mutect2, varscan2
- CYP2C19 | c.1439del p.P480Rfs*54 | Frame Shift Del (DEL) | VAF 102/191 reads (53%) | catalogued as COSV64908867; called by mutect2, pindel, varscan2
- DMXL1 | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 164/238 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60704629, COSV60705715; called by muse, mutect2, varscan2
- DNAH8 | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 63/184 reads (34%) | catalogued as COSV59423856; called by muse, mutect2, varscan2
- DNAI1 | c.1219A>C p.N407H | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV54278284; called by muse, mutect2, varscan2
- DOCK11 | c.4115G>T p.S1372I | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.797); catalogued as COSV52233461; called by muse, mutect2, varscan2
- DRP2 | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 209/317 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65809206; called by muse, mutect2, varscan2
- DYRK1A | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100117945, COSV58292283; called by muse, mutect2
- EARS2 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71942744; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57514450; called by muse, mutect2, varscan2
- EIF4G3 | c.4658A>G p.K1553R | Missense Mutation (SNP) | VAF 159/411 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV51673822; called by muse, mutect2, varscan2
- ELAVL4 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV63914145, COSV63917460; called by muse, mutect2, varscan2
- EPB41L3 | c.3010A>T p.M1004L | Missense Mutation (SNP) | VAF 151/472 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as COSV59443974; called by muse, mutect2, varscan2
- EPB41L3 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 137/330 reads (42%) | catalogued as COSV59444001; called by muse, varscan2
- ESF1 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs1156518434, COSV52518883; called by muse, mutect2, varscan2
- ESPNL | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV58032070; called by mutect2, varscan2
- ESRRB | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55058410; called by muse, mutect2, varscan2
- FAN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 237/321 reads (74%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100755819, COSV62949645; called by muse, mutect2, varscan2
- FCRL5 | c.2183A>T p.E728V | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62511319; called by muse, mutect2, varscan2
- FDXR | c.962G>T p.R321L (on ENST00000293195 / NM_024417.5; = p.R327L on NM_004110.6) | Missense Mutation (SNP) | VAF 83/120 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1179210362, COSV53109690; called by muse, mutect2, varscan2
- FOXP1 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV59534822; called by muse, mutect2, varscan2
- FSCB | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 263/544 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV61216474; called by muse, varscan2
- GALNT13 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV67209680; called by muse, mutect2, varscan2
- GGPS1 | c.887A>T p.K296I | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV51396858, COSV51398025; called by muse, mutect2, varscan2
- GLRA4 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65455089; called by muse, mutect2
- GLYR1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 103/143 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58925510; called by muse, mutect2, varscan2
- GRID1 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 138/189 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60013642; called by muse, mutect2, varscan2
- GRIK3 | c.521C>A p.S174* | Nonsense Mutation (SNP) | VAF 379/833 reads (45%) | catalogued as COSV66135373; called by muse, mutect2, varscan2
- GRM2 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237497654, COSV56583150; called by muse, mutect2, varscan2
- GTF2H4 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV52557614; called by muse, mutect2, varscan2
- H6PD | c.2279G>T p.R760L | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs933325977, COSV66230156; called by muse, mutect2, varscan2
- HCN1 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV57493385, COSV57515422; called by muse, mutect2, varscan2
- HDAC9 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 131/229 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101286696, COSV67766526; called by muse, mutect2, varscan2
- HERC2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 105/149 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV55306961; called by muse, mutect2, varscan2
- HERC2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 103/149 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV55306991; called by muse, mutect2, varscan2
- HOGA1 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 115/490 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65706247; called by muse, varscan2
- HPS6 | c.1485G>T p.R495S | Missense Mutation (SNP) | VAF 117/165 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV54624830; called by muse, mutect2, varscan2
- HTR2C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/21 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV52201240; called by muse, mutect2, varscan2
- IDH1 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100577071; called by muse, mutect2
- IFIH1 | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV55124552; called by muse, mutect2, varscan2
- IFT172 | c.4634C>T p.S1545F | Missense Mutation (SNP) | VAF 93/666 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV53129556; called by muse, mutect2, varscan2
- IGLC7 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as rs1438368869; called by muse, mutect2, varscan2
- IGLON5 | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54534458; called by muse, mutect2, varscan2
- IGSF21 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52125245; called by muse, mutect2, varscan2
- IL32 | c.358G>C p.E120Q (on ENST00000396890 / NM_001308078.4; = p.E74Q on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1567149523, COSV50403603; called by muse, mutect2, varscan2
- IPO8 | c.3019G>A p.A1007T | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1165257174, COSV56239472; called by muse, mutect2, varscan2
- IQGAP3 | c.2321A>G p.Y774C | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); catalogued as COSV63249059; called by muse, mutect2, varscan2
- IVL | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.206); catalogued as COSV64215465; called by muse, varscan2
- KATNAL2 | c.544C>T p.R182* (on ENST00000356157 / NM_001353899.1; = p.R110* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 79/235 reads (34%) | catalogued as rs757847286, COSV55293162; called by muse, mutect2, varscan2
- KCNJ14 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374178623; called by muse, mutect2, varscan2
- KLHL32 | c.356del p.G119Afs*21 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | catalogued as COSV100987111; called by mutect2, pindel, varscan2
- KNL1 | c.6976G>T p.V2326L (on ENST00000346991 / NM_170589.5; = p.V2300L on NM_144508.5) | Missense Mutation (SNP) | VAF 380/491 reads (77%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as rs1327765644, COSV61150941; called by muse, mutect2, varscan2
- LAPTM5 | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV53852338; called by muse, mutect2
- LCE2D | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 347/585 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV64228816; called by muse, mutect2, varscan2
- LCE2D | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 345/584 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as rs754335373, COSV64228820, COSV64228862; called by muse, mutect2, varscan2
- LCT | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 78/631 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51543939; called by muse, mutect2, varscan2
- LRFN5 | c.968C>G p.P323R | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53242637; called by muse, mutect2, varscan2
- LRP11 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53332932; called by muse, mutect2, varscan2
- LRP1B | c.13285C>A p.P4429T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.261); catalogued as COSV67185230; called by muse, mutect2, varscan2
- LRP1B | c.11350C>G p.L3784V | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV67185233; called by muse, mutect2, varscan2
- LRP1B | c.8776C>A p.H2926N | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146247369; called by muse, mutect2, varscan2
- LRRC19 | c.483T>A p.D161E | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV66259307; called by muse, mutect2, varscan2
- LRRIQ3 | c.1584G>T p.L528F | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV63040992; called by muse, mutect2, varscan2
- LRRK2 | c.6525C>A p.D2175E | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV54143195; called by muse, mutect2, varscan2
- MAGEA6 | c.857T>A p.V286D | Missense Mutation (SNP) | VAF 337/494 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61448659; called by muse, mutect2, varscan2
- MBD1 | c.1367T>G p.L456R (on ENST00000269468 / NM_001323950.1; = p.L400R on NM_002384.2) | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV53997953; called by muse, varscan2
- MGAT4C | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59829749; called by muse, mutect2, varscan2
- MOCOS | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.888); catalogued as COSV54340853; called by muse, mutect2, varscan2
- MORC4 | c.2657A>T p.E886V | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV55239372; called by muse, mutect2
- MUC17 | c.1933del p.E645Rfs*16 | Frame Shift Del (DEL) | VAF 297/1458 reads (20%) | catalogued as COSV100071059, COSV60287714; called by mutect2, pindel, varscan2
- MYH2 | c.5011G>T p.E1671* | Nonsense Mutation (SNP) | VAF 100/156 reads (64%) | catalogued as COSV55431342; called by muse, mutect2, varscan2
- MYH2 | c.5010G>T p.Q1670H | Missense Mutation (SNP) | VAF 100/155 reads (65%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as COSV55431350; called by muse, mutect2, varscan2
- NAP1L2 | c.949C>G p.P317A | Missense Mutation (SNP) | VAF 13/347 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65172152, COSV65172215, COSV65172507; called by muse, mutect2
- NBEAL1 | c.7892A>G p.H2631R | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as COSV68915487; called by muse, mutect2, varscan2
- NBN | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV55371035; called by muse, mutect2, varscan2
- NEK10 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV55354927; called by muse, mutect2, varscan2
- NF1 | c.6691G>T p.E2231* (on ENST00000358273 / NM_001042492.3; = p.E2210* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 44/63 reads (70%) | catalogued as CM000814, COSV62192689, COSV62219494; called by muse, mutect2, varscan2
- NLGN3 | c.1933A>G p.T645A (on ENST00000358741 / NM_181303.2; = p.T625A on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV62441635; called by muse, mutect2, varscan2
- NLRP5 | c.2274A>G p.L758= | Splice Region (SNP) | VAF 292/765 reads (38%) | catalogued as rs770308622, COSV66761966; called by muse, mutect2, varscan2
- NOL8 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781447196, COSV62634048; called by muse, mutect2, varscan2
- NTN4 | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100643718, COSV59217044; called by muse, mutect2, varscan2
- OR10G4 | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 278/477 reads (58%) | catalogued as COSV57976553; called by muse, mutect2, varscan2
- OR2B3 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.645); catalogued as COSV65850721; called by muse, mutect2, varscan2
- OR2M2 | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 429/766 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV62897744; called by muse, varscan2
- OR2T29 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60771126; called by muse, mutect2, varscan2
- OR2T6 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775649803, COSV63216213; called by muse, mutect2, varscan2
- OR51G2 | c.364T>C p.S122P | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58991767; called by muse, mutect2, varscan2
- OR56A1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 104/149 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs770347649, COSV57361741; called by muse, mutect2, varscan2
- OR5AU1 | c.218A>T p.Y73F | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV58615237; called by muse, mutect2, varscan2
- OR5AU1 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV58615243; called by muse, mutect2, varscan2
- OR5H1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63402059, COSV63403022; called by muse, mutect2, varscan2
- OR5H6 | c.596C>A p.P199Q (on ENST00000642105; = p.P183Q on NM_001005479.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as COSV101051795; called by muse, mutect2, varscan2
- OR8B3 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 93/120 reads (78%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1290154714, COSV100660419; called by muse, mutect2, varscan2
- OR9Q1 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 220/318 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV59036515; called by muse, mutect2, varscan2
- OSBPL10 | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as COSV67335984; called by muse, mutect2, varscan2
- PATJ | c.2793T>G p.Y931* | Nonsense Mutation (SNP) | VAF 93/237 reads (39%) | catalogued as COSV57155221; called by muse, mutect2, varscan2
- PCDH9 | c.1667C>A p.A556E | Missense Mutation (SNP) | VAF 191/261 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753210691, COSV60527839, COSV60592737; called by muse, mutect2, varscan2
- PCDHA2 | c.888T>A p.D296E | Missense Mutation (SNP) | VAF 202/263 reads (77%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.178); catalogued as COSV65364497; called by muse, mutect2, varscan2
- PDE11A | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 145/300 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV53686012; called by muse, mutect2, varscan2
- PGAP1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61323673; called by muse, mutect2, varscan2
- PGAP1 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61323680; called by muse, mutect2, varscan2
- PGBD2 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs775771671, COSV61399561; called by muse, mutect2, varscan2
- PIP5K1C | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as COSV58950069; called by muse, mutect2, varscan2
- PKD1 | c.8570C>A p.A2857D | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV51910514; called by muse, mutect2, varscan2
- PKHD1L1 | c.7826G>A p.G2609D | Missense Mutation (SNP) | VAF 193/248 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375856975; called by muse, mutect2, varscan2
- PKHD1L1 | c.8080G>A p.G2694R | Missense Mutation (SNP) | VAF 149/212 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV65736853; called by muse, mutect2, varscan2
- PLEKHG2 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV52678075; called by muse, mutect2, varscan2
- PLP1 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 439/686 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58275563, COSV58277912; called by muse, mutect2, varscan2
- PNMA8A | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV58135609; called by muse, mutect2, varscan2
- PNPT1 | c.2014-2A>T p.X672_splice | Splice Site (SNP) | VAF 72/138 reads (52%) | catalogued as COSV53175624; called by muse, mutect2, varscan2
- PON1 | c.573A>T p.L191F | Missense Mutation (SNP) | VAF 119/204 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV55930610; called by muse, mutect2, varscan2
- PRR19 | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 72/447 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV56623782; called by muse, mutect2, varscan2
- PRR23B | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 79/477 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61493133, COSV61493421; called by muse, mutect2, varscan2
- PTCHD4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV59777400; called by muse, mutect2, varscan2
- PTGDR | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 130/454 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV60093042, COSV60093384; called by muse, mutect2, varscan2
- PTPRD | c.3530G>T p.R1177L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs763141884, COSV61927867, COSV61939245; called by muse, mutect2, varscan2
- PTPRU | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV60521584; called by muse, mutect2, varscan2
- PXDNL | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62477579; called by muse, mutect2, varscan2
- QSOX2 | c.200A>C p.D67A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1554758429, COSV62393340; called by muse, mutect2, varscan2
- RASGRF2 | c.3005C>T p.S1002L | Missense Mutation (SNP) | VAF 89/128 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs747408294, COSV54122616; called by muse, mutect2, varscan2
- RASGRP3 | c.1012A>T p.S338C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV67820362; called by muse, mutect2, varscan2
- REPS1 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57808656; called by muse, mutect2, varscan2
- RHOU | c.263C>A p.A88E | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100797197, COSV64208255; called by muse, mutect2, varscan2
- RNF146 | c.1013G>A p.G338D (on ENST00000368314 / NM_001242850.2; = p.G337D on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1385453880, COSV58931342, COSV58931733; called by muse, mutect2, varscan2
- RRM2B | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 113/137 reads (82%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as COSV52565506; called by muse, mutect2, varscan2
- SALL3 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs371427282; called by muse, mutect2, varscan2
- SAMD7 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 502/672 reads (75%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs764134487, COSV59416968; called by muse, mutect2, varscan2
- SCAP | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 78/134 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.739); catalogued as COSV55558738; called by muse, mutect2, varscan2
- SCNN1D | c.1388C>A p.S463Y (on ENST00000338555; = p.S627Y on NM_001130413.4) | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57639748, COSV57640346; called by muse, mutect2, varscan2
- SCUBE1 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 113/329 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62610088; called by muse, mutect2, varscan2
- SIGLEC10 | c.1108G>C p.V370L | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV59478736; called by muse, mutect2, varscan2
- SIN3A | c.2771G>C p.R924T | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV64581683; called by muse, mutect2, varscan2
- SIPA1L2 | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 96/158 reads (61%) | catalogued as COSV53383329; called by muse, mutect2, varscan2
- SLC18A3 | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1344348757, COSV100340283, COSV60319977, COSV60332384; called by muse, mutect2, varscan2
- SLC24A5 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 142/194 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58316123; called by muse, varscan2
- SLC27A6 | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52479237; called by muse, mutect2, varscan2
- SLCO1C1 | c.1063T>G p.Y355D | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56868192; called by muse, mutect2, varscan2
- SLFN11 | c.1723A>T p.N575Y | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1197126228, COSV100390807; called by muse, mutect2
- SMC1A | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV59127642; called by muse, mutect2, varscan2
- SNIP1 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56165551; called by muse, mutect2, varscan2
- SPTBN2 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 103/138 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59446419; called by muse, mutect2, varscan2
- SRPX | c.696A>T p.E232D | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59437157; called by muse, mutect2
- ST8SIA6 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373503230; called by muse, mutect2, varscan2
- STAG3 | c.1165-2A>G p.X389_splice | Splice Site (SNP) | VAF 52/256 reads (20%) | catalogued as COSV57927418; called by muse, mutect2, varscan2
- STIL | c.889G>T p.G297* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV54547524; called by muse, mutect2, varscan2
- SUZ12 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 177/232 reads (76%) | catalogued as COSV59497789; called by muse, mutect2, varscan2
- TAAR5 | c.556A>T p.M186L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57798445; called by muse, mutect2, varscan2
- TARS1 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 225/349 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV54307420; called by muse, mutect2, varscan2
- TBX5 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 109/167 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs746726123, COSV59858380; called by muse, mutect2, varscan2
- TEK | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV101193484; called by muse, varscan2
- TEK | c.1049C>A p.P350Q | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV101193485; called by muse, varscan2
- TEKT2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141019195; called by muse, mutect2, varscan2
- TEP1 | c.2685-1G>C p.X895_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | catalogued as COSV52987910; called by muse, mutect2, varscan2
- THOP1 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs753980550, COSV57017590; called by muse, mutect2, varscan2
- THSD7A | c.2800G>T p.G934* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | catalogued as COSV70260084; called by muse, mutect2, varscan2
- TMEM176B | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 108/213 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs762868592, COSV58438730; called by muse, mutect2, varscan2
- TNPO1 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61520160; called by muse, mutect2, varscan2
- TRBV4-1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 110/201 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as rs776438528; called by muse, mutect2, varscan2
- TRPM3 | c.882C>A p.F294L (on ENST00000357533 / NM_001366142.2; = p.F139L on NM_020952.6) | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62467249; called by muse, mutect2, varscan2
- TSC1 | c.2904G>T p.R968S | Missense Mutation (SNP) | VAF 200/505 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53763544; called by muse, mutect2, varscan2
- TSHZ2 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs867955592, COSV61586761; called by muse, mutect2, varscan2
- TSHZ2 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61586770; called by muse, mutect2, varscan2
- TSKS | c.1120C>G p.R374G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.257); catalogued as COSV104370647, COSV55872740; called by muse, mutect2, varscan2
- TTLL2 | c.486C>A p.H162Q | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as rs371348357, COSV53442498; called by muse, mutect2, varscan2
- TTN | c.33639A>T p.K11213N (on ENST00000591111; = p.K10286N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | PolyPhen possibly damaging (0.691); catalogued as COSV59881088, COSV60140429; called by muse, mutect2, varscan2
- TTN | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 89/195 reads (46%) | PolyPhen probably damaging (0.966); catalogued as COSV59881141; called by muse, mutect2, varscan2
- TTYH1 | c.411C>A p.D137E | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV56609585; called by muse, mutect2, varscan2
- TTYH1 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as rs1041833558, COSV56609597; called by muse, mutect2, varscan2
- TTYH3 | c.1020+1G>T p.X340_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV51858490; called by mutect2, varscan2
- UBE2D1 | c.303A>T p.K101N | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV64218105; called by muse, mutect2, varscan2
- UBE3C | c.2522G>T p.G841V | Missense Mutation (SNP) | VAF 154/557 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV61950939; called by muse, mutect2, varscan2
- UCP3 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs58614015, COSV58367481; called by muse, mutect2, varscan2
- UGT2A3 | c.884A>G p.Q295R | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV52358741; called by muse, mutect2, varscan2
- UNC13B | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as COSV65931220; called by muse, mutect2, varscan2
- UNC13B | c.2715G>A p.M905I | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV65931224; called by muse, mutect2, varscan2
- UNC13B | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV65931227; called by muse, mutect2, varscan2
- USP15 | c.2054G>A p.G685E (on ENST00000280377 / NM_001351159.2; = p.G656E on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV54787506; called by muse, mutect2, varscan2
- UTRN | c.9277G>A p.V3093I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.122); catalogued as COSV62303548; called by muse, mutect2, varscan2
- WDR12 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV53686285; called by muse, mutect2, varscan2
- WIZ | c.4025G>T p.G1342V (on ENST00000673675 / NM_001371589.1; = p.G247V on NM_021241.3) | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV54604554; called by muse, mutect2, varscan2
- XAGE5 | c.72+2T>C p.X24_splice | Splice Site (SNP) | VAF 15/333 reads (5%) | catalogued as COSV63567562; called by muse, mutect2
- XIRP2 | c.8533G>A p.E2845K (on ENST00000628543; = p.E3020K on NM_152381.6) | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as rs780833909, COSV54681929, COSV99739811; called by muse, mutect2, varscan2
- ZAN | c.2761A>G p.T921A | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV61804797; called by muse, varscan2
- ZBTB18 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV62396263; called by muse, mutect2, varscan2
- ZNF566 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.335); catalogued as COSV67573208; called by muse, mutect2, varscan2
- ZNF639 | c.1426A>T p.I476L | Missense Mutation (SNP) | VAF 133/188 reads (71%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV58382697; called by muse, mutect2, varscan2
- ZNF646 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV56211265; called by muse, mutect2, varscan2
- ZNF646 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV54922583; called by muse, mutect2, varscan2
- ZNF646 | c.3995C>A p.P1332H | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99762481; called by muse, mutect2
- ZNF675 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV63094885; called by muse, mutect2, varscan2
- ZNF804A | c.3500C>T p.P1167L | Missense Mutation (SNP) | VAF 197/384 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV56435111; called by muse, mutect2, varscan2
- ZNF83 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV56528393; called by muse, mutect2, varscan2
- ABCA9 | c.2074_2075insT p.G692Vfs*13 | Frame Shift Ins (INS) | VAF 307/511 reads (60%) | called by mutect2, pindel, varscan2
- APLNR | c.332del p.V111Afs*22 | Frame Shift Del (DEL) | VAF 42/58 reads (72%) | called by mutect2, pindel*, varscan2
- DHX34 | c.2488del p.H830Tfs*43 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.3302A>T p.Q1101L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- GALR1 | c.935del p.K312Rfs*17 | Frame Shift Del (DEL) | VAF 65/213 reads (31%) | called by mutect2, pindel, varscan2
- MBD1 | c.1381del p.E461Kfs*29 (on ENST00000269468 / NM_001323950.1; = p.E405Kfs*24 on NM_002384.2) | Frame Shift Del (DEL) | VAF 58/184 reads (32%) | called by pindel, varscan2
- MRPL34 | c.182del p.K61Rfs*10 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel
- PNMA2 | c.638del p.P213Lfs*8 | Frame Shift Del (DEL) | VAF 108/302 reads (36%) | called by pindel, varscan2*
- POTEA | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 150/217 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PPIAL4A | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 96/809 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SUPT20HL1 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 28/968 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2
- USP22 | c.1393_1394del p.L465Vfs*5 | Frame Shift Del (DEL) | VAF 155/241 reads (64%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.660G>T p.L220= | Silent (SNP) | VAF 21/222 reads (9%) | catalogued as COSV61464173; called by muse, mutect2, varscan2
- C16orf71 | c.594C>T p.A198= | Silent (SNP) | VAF 94/136 reads (69%) | catalogued as rs751623429, COSV73918448; called by muse, mutect2, varscan2
- CANT1 | c.522T>C p.N174= | Silent (SNP) | VAF 485/652 reads (74%) | catalogued as rs368203123; called by muse, mutect2, varscan2
- CDH16 | c.402G>A p.R134= | Silent (SNP) | VAF 62/88 reads (70%) | catalogued as rs756422642, COSV55334752; called by muse, mutect2, varscan2
- CELSR3 | c.1251G>A p.T417= | Silent (SNP) | VAF 56/103 reads (54%) | catalogued as COSV50839820; called by muse, mutect2, varscan2
- CHST3 | c.291C>A p.L97= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV64150339; called by muse, mutect2, varscan2
- CIDEA | c.489C>T p.C163= | Silent (SNP) | VAF 92/223 reads (41%) | catalogued as COSV57597313; called by muse, mutect2, varscan2
- DOCK10 | c.1716G>A p.V572= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1200537905, COSV51347538; called by muse, mutect2, varscan2
- DPP10 | c.30C>T p.H10= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV69738752; called by muse, mutect2, varscan2
- DTX3L | c.861G>A p.L287= | Silent (SNP) | VAF 67/100 reads (67%) | catalogued as COSV56143195; called by muse, mutect2, varscan2
- FBN2 | c.3369T>A p.P1123= | Silent (SNP) | VAF 107/147 reads (73%) | catalogued as rs758977496, COSV52492270; called by muse, mutect2, varscan2
- GPRIN3 | c.2127C>A p.I709= | Silent (SNP) | VAF 73/99 reads (74%) | catalogued as COSV60884046; called by muse, mutect2, varscan2
- GRM8 | c.2058G>C p.A686= | Silent (SNP) | VAF 51/93 reads (55%) | catalogued as COSV58800842, COSV58872504; called by muse, mutect2, varscan2
- ITIH5 | c.672A>T p.P224= | Silent (SNP) | VAF 60/72 reads (83%) | catalogued as COSV53659570; called by muse, mutect2, varscan2
- JCAD | c.1761G>A p.V587= | Silent (SNP) | VAF 213/445 reads (48%) | catalogued as COSV64757876; called by muse, mutect2, varscan2
- JUN | c.204G>T p.L68= | Silent (SNP) | VAF 145/462 reads (31%) | catalogued as COSV64664155; called by muse, mutect2, varscan2
- KCNJ12 | c.630C>T p.C210= | Silent (SNP) | VAF 47/74 reads (64%) | catalogued as COSV59163238; called by muse, mutect2, varscan2
- LRRC41 | c.291C>T p.L97= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV58438851; called by muse, mutect2, varscan2
- LRRIQ4 | c.600A>T p.I200= | Silent (SNP) | VAF 152/1091 reads (14%) | catalogued as COSV61618611; called by muse, mutect2, varscan2
- MACO1 | c.486T>A p.P162= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV65474999; called by muse, mutect2, varscan2
- MERTK | c.1596A>C p.T532= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV54924372; called by muse, mutect2, varscan2
- MYH4 | c.5259C>T p.R1753= | Silent (SNP) | VAF 322/418 reads (77%) | catalogued as COSV55111987; called by muse, mutect2, varscan2
- NCKAP1L | c.813C>T p.L271= | Silent (SNP) | VAF 74/201 reads (37%) | catalogued as rs1408846758, COSV53203280; called by muse, mutect2, varscan2
- NEUROD1 | c.714T>C p.H238= | Silent (SNP) | VAF 126/257 reads (49%) | catalogued as rs770828405, COSV54548111; called by muse, mutect2, varscan2
- OR2G6 | c.303C>G p.L101= | Silent (SNP) | VAF 167/318 reads (53%) | catalogued as rs750445385, COSV58573650; called by muse, mutect2, varscan2
- OR4M1 | c.309C>T p.F103= | Silent (SNP) | VAF 233/705 reads (33%) | catalogued as COSV60059358; called by muse, mutect2, varscan2
- OR4N2 | c.213A>G p.A71= | Silent (SNP) | VAF 100/693 reads (14%) | catalogued as COSV60049906; called by muse, mutect2
- OR6B1 | c.450C>A p.A150= | Silent (SNP) | VAF 54/80 reads (68%) | catalogued as COSV68769778; called by muse, mutect2, varscan2
- PACRG | c.546G>T p.V182= | Silent (SNP) | VAF 90/210 reads (43%) | catalogued as COSV61296147; called by muse, mutect2, varscan2
- PARP14 | c.42C>T p.S14= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1246501750, COSV72111678; called by muse, mutect2, varscan2
- PIK3AP1 | c.618G>A p.V206= | Silent (SNP) | VAF 202/307 reads (66%) | catalogued as COSV59530235; called by muse, mutect2, varscan2
- PLA2G3 | c.807C>A p.P269= | Silent (SNP) | VAF 86/230 reads (37%) | catalogued as COSV53207524; called by muse, mutect2, varscan2
- PRDM14 | c.750A>G p.P250= | Silent (SNP) | VAF 164/207 reads (79%) | catalogued as COSV52570554; called by muse, mutect2, varscan2
- PSMD1 | c.852G>T p.T284= | Silent (SNP) | VAF 82/171 reads (48%) | catalogued as COSV58076120; called by muse, mutect2, varscan2
- PYGO2 | c.333G>A p.A111= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs550049773, COSV63756583; called by muse, mutect2, varscan2
- RTTN | c.1203G>A p.V401= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV55341073; called by muse, mutect2, varscan2
- SLC28A3 | c.1401C>G p.A467= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV66152036; called by muse, mutect2
- SLC40A1 | c.552C>T p.T184= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV53721817; called by muse, mutect2, varscan2
- SNRNP25 | c.378C>T p.I126= (on ENST00000383018; = p.I117= on NM_024571.4) | Silent (SNP) | VAF 74/489 reads (15%) | catalogued as COSV51953456; called by muse, mutect2, varscan2
- SPTB | c.1275G>T p.R425= | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as COSV67629724; called by muse, mutect2, varscan2
- SSTR3 | c.468A>T p.T156= | Silent (SNP) | VAF 109/266 reads (41%) | catalogued as COSV60728583; called by muse, mutect2, varscan2
- SSX7 | c.255T>C p.D85= | Silent (SNP) | VAF 209/324 reads (65%) | catalogued as COSV53339213; called by muse, mutect2, varscan2
- SUPV3L1 | c.1497G>A p.K499= | Silent (SNP) | VAF 14/189 reads (7%) | catalogued as rs1404267353, COSV62844562; called by muse, mutect2
- SZT2 | c.5460C>T p.P1820= (on ENST00000634258 / NM_001365999.1; = p.P1763= on NM_015284.4) | Silent (SNP) | VAF 127/469 reads (27%) | catalogued as COSV65167153, COSV65173616; called by muse, mutect2, varscan2
- TAS2R31 | c.405G>T p.G135= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as COSV101115568, COSV66829756; called by muse, mutect2, varscan2
- TRPM8 | c.72G>T p.L24= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV61220546; called by muse, mutect2, varscan2
- TTN | c.100842T>G p.S33614= (on ENST00000591111; = p.S26190= on NM_003319.4) | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as COSV59881047; called by muse, mutect2, varscan2
- TTN | c.13245G>A p.Q4415= (on ENST00000591111; = p.Q4369= on NM_003319.4) | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV59881103; called by muse, mutect2, varscan2
- UGT2A3 | c.1035A>G p.L345= | Silent (SNP) | VAF 40/54 reads (74%) | catalogued as COSV52358730; called by muse, mutect2, varscan2
- USP51 | c.2124A>G p.L708= | Silent (SNP) | VAF 79/113 reads (70%) | catalogued as COSV72351445; called by muse, mutect2, varscan2
- WHRN | c.1245G>C p.L415= | Silent (SNP) | VAF 47/114 reads (41%) | catalogued as COSV54326858, COSV99470219; called by muse, mutect2, varscan2
- ZAP70 | c.1068G>C p.V356= | Silent (SNP) | VAF 133/240 reads (55%) | catalogued as COSV53852434; called by muse, mutect2, varscan2
- ZNF646 | c.2578C>T p.L860= | Silent (SNP) | VAF 43/251 reads (17%) | catalogued as COSV54922577; called by muse, mutect2, varscan2
- ZNF85 | c.1704T>C p.C568= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV60213184; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823159 A>T | 5'Flank (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- DDHD1 | chr14:53152444 T>A | 5'Flank (SNP) | VAF 24/82 reads (29%) | catalogued as COSV60357070; called by muse, mutect2, varscan2
- DPP6 | c.627+20850C>T | Intron (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100126655; called by muse, mutect2, varscan2
- FBXL13 | c.496-5646G>T | Intron (SNP) | VAF 33/53 reads (62%) | catalogued as COSV100501880; called by muse, mutect2, varscan2
- H2BP2 | chr1:143874818 T>C | 3'Flank (SNP) | VAF 14/66 reads (21%) | called by mutect2, varscan2
- PCDH11X | n.560G>C | RNA (SNP) | VAF 33/51 reads (65%) | called by muse, mutect2, varscan2
- PRR12 | c.51+329G>A | Intron (SNP) | VAF 24/56 reads (43%) | catalogued as rs775761988, COSV55869490; called by muse, mutect2, varscan2
- REXO1L1P | n.1515C>G | RNA (SNP) | VAF 14/198 reads (7%) | called by muse, varscan2
- SLC17A3 | c.304-96G>A | Intron (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100399274; called by muse, mutect2, varscan2
- TOX3 | c.*302G>A | 3'UTR (SNP) | VAF 29/42 reads (69%) | catalogued as COSV99567199, COSV99567842; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23276G>A | Intron (SNP) | VAF 128/644 reads (20%) | catalogued as rs761738753, COSV59381483; called by muse, mutect2, varscan2
- ZNF99 | c.*701A>T | 3'UTR (SNP) | VAF 33/40 reads (83%) | catalogued as COSV68054679; called by muse, varscan2
- ZNF99 | c.*319T>A | 3'UTR (SNP) | VAF 45/103 reads (44%) | catalogued as COSV68054685; called by muse, mutect2, varscan2
